Somatic mutation profile of tumor specimen TCGA-76-4935-01A (aliquot TCGA-76-4935-01A-01D-1486-08) from TCGA case TCGA-76-4935, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,231 days).
Specimen TCGA-76-4935-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1683650-d0ce-4ee8-917c-400ac3644323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4935-10A (Blood Derived Normal), aliquot TCGA-76-4935-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cda09677-0dcf-4b94-8187-a1d5da6edd7b

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.956_959del p.T319Kfs*24 | Frame Shift Del (DEL) | VAF 97/128 reads (76%) | catalogued as rs398123330, COSV64288731; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL4 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV66107219; called by muse, mutect2, varscan2
- ABCB5 | c.3124C>T p.R1042* (on ENST00000404938 / NM_001163941.2; = p.R597* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 17/160 reads (11%) | catalogued as rs201925737; called by muse, mutect2
- ABCC9 | c.3229A>G p.I1077V | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.204); catalogued as COSV53986945; called by muse, mutect2
- ABCD1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1258368672, COSV54386662; called by muse, mutect2, varscan2
- AFF2 | c.3477C>T p.C1159= | Splice Region (SNP) | VAF 110/248 reads (44%) | catalogued as COSV54008433; called by muse, mutect2, varscan2
- ANKFY1 | c.2221G>A p.A741T (on ENST00000341657 / NM_001330063.2; = p.A742T on NM_016376.5) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs751831487, COSV58915730, COSV58923231; called by muse, mutect2, varscan2
- ARHGEF28 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs772380154, COSV55270901; called by muse, mutect2, varscan2
- D2HGDH | c.458T>C p.M153T | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM0910128, COSV58323513; called by muse, mutect2
- DAXX | c.1991G>T p.C664F | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.155); catalogued as COSV56472868; called by muse, mutect2, varscan2
- DYRK4 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV50545295; called by muse, mutect2
- ERICH3 | c.2477C>G p.T826R | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as COSV58618855; called by muse, mutect2, varscan2
- FAM110B | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403549188, COSV100826126, COSV64068214; called by muse, mutect2, varscan2
- FAM83H | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs572494015, COSV62027497; called by muse, mutect2, varscan2
- GIMAP1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs374968861, COSV56188394; called by muse, mutect2, varscan2
- GOLGA4 | c.3472G>A p.V1158I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs770853087, COSV62713970; called by muse, mutect2, varscan2
- HCN1 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV57524543; called by muse, mutect2, varscan2
- HERPUD1 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.535); catalogued as COSV55863739; called by muse, mutect2, varscan2
- HNF1A | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56568598, COSV56568795; called by muse, mutect2, varscan2
- KIF2B | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52135555; called by muse, mutect2
- KLHL34 | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1464771579, COSV65279204, COSV65280308; called by muse, mutect2, varscan2
- LCOR | c.3461G>T p.R1154M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53718573; called by mutect2, varscan2
- MAN2B1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55472202; called by muse, mutect2, varscan2
- MAP3K15 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as COSV100133854; called by muse, mutect2
- MTMR11 | c.653C>T p.T218M (on ENST00000439741 / NM_001145862.2; = p.T146M on NM_181873.3) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs368805416; called by muse, mutect2, varscan2
- MXRA5 | c.3533A>G p.E1178G | Missense Mutation (SNP) | VAF 112/275 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54251297; called by muse, mutect2, varscan2
- MYH13 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV52843385; called by muse, mutect2, varscan2
- OR2A1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 78/749 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs750474119, COSV68822756; called by muse, mutect2, varscan2
- OTOA | c.1474G>A p.V492I (on ENST00000286149; = p.V478I on NM_144672.4) | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs572283930, COSV53764820; called by muse, mutect2, varscan2
- OTOGL | c.4847G>A p.R1616Q (on ENST00000547103; = p.R1607Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1225111265, COSV100086441; called by muse, mutect2, varscan2
- PIP5K1B | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV55258243; called by muse, mutect2, varscan2
- PLXNA2 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV65445127; called by muse, mutect2, varscan2
- PPP1R3A | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); catalogued as rs200605903; called by muse, mutect2, varscan2
- RAI2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 122/304 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs373934341, COSV58966321; called by muse, mutect2, varscan2
- SPEG | c.5212C>T p.R1738W | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1401200569, COSV56678394; called by muse, mutect2, varscan2
- SRBD1 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1209270160, COSV55401215, COSV55405655; called by muse, mutect2, varscan2
- TEX13B | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 23/371 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV57203888; called by muse, mutect2
- ZFHX4 | c.9098C>G p.S3033* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | catalogued as COSV51497173; called by muse, mutect2, varscan2
- ZFYVE26 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV61333694; called by muse, mutect2
- TBX5 | c.1546_1556del p.D516Kfs*2 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- CSTF2 | c.30G>T p.A10= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV63376541; called by muse, mutect2, varscan2
- DUSP21 | c.246C>T p.Y82= | Silent (SNP) | VAF 75/198 reads (38%) | catalogued as rs369441582, COSV59133653; called by muse, mutect2, varscan2
- EDA2R | c.816G>A p.E272= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53633143; called by muse, mutect2
- FOXI1 | c.684C>A p.S228= | Silent (SNP) | VAF 13/183 reads (7%) | catalogued as COSV60390151; called by muse, mutect2
- GALNT5 | c.2628A>G p.R876= | Silent (SNP) | VAF 105/244 reads (43%) | catalogued as COSV52041421; called by muse, mutect2, varscan2
- KIF2B | c.183G>T p.V61= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV52129276, COSV52135544; called by muse, mutect2
- MTMR1 | c.1872C>A p.V624= | Silent (SNP) | VAF 21/189 reads (11%) | catalogued as COSV60938597; called by muse, mutect2, varscan2
- NOX5 | c.1107G>A p.P369= | Silent (SNP) | VAF 54/214 reads (25%) | catalogued as rs1484299977, COSV52996370; called by muse, mutect2, varscan2
- PCDH11X | c.3828C>A p.V1276= | Silent (SNP) | VAF 205/469 reads (44%) | catalogued as COSV100010621, COSV53442672; called by muse, mutect2, varscan2
- SPATA31E1 | c.2481C>G p.L827= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV57795425; called by muse, mutect2
- SPTBN5 | c.1287G>T p.R429= | Silent (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- TRPC5 | c.2391C>T p.V797= | Silent (SNP) | VAF 72/572 reads (13%) | catalogued as COSV53303344; called by muse, mutect2, varscan2
- VIL1 | c.810C>T p.V270= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as rs148795202; called by muse, mutect2
- MIR424 | n.54G>A | RNA (SNP) | VAF 23/50 reads (46%) | called by muse, varscan2
